Somatic mutation profile of tumor specimen ALCH-B277-TTP1-A (aliquot ALCH-B277-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B277, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.9 years (24,088 days).
Specimen ALCH-B277-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2293733-094c-45fb-a657-972684ec93de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B277-NB1-A (Blood Derived Normal), aliquot ALCH-B277-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4555a9d0-e040-42d5-a769-cce7510e74bf

The open-access MAF lists 114 somatic variants for this specimen: 81 protein-altering or splice-affecting, 20 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 20, Frame Shift Del 5, Intron 5, Nonsense Mutation 4, RNA 3, 3'UTR 3, 5'Flank 1, In Frame Ins 1, 3'Flank 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 67/199 reads (34%) | catalogued as rs121913383, COSV58683264, COSV58724303, COSV58727969; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 154/363 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCG5 | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1301882747; called by muse, mutect2, varscan2
- ARID2 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 39/98 reads (40%) | catalogued as COSV57596634; called by muse, mutect2
- BOC | c.3310C>T p.R1104C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs145326895, COSV56356981; called by muse, mutect2, varscan2
- CACNA2D3 | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs770327152; called by muse, mutect2, varscan2
- CHM | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as rs1272374695; called by muse, mutect2
- CHM | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV62566097; called by muse, mutect2
- CSRNP1 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 95/293 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV56188652, COSV56189893; called by muse, mutect2, varscan2
- CYLD | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 79/525 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV61095659; called by muse, mutect2, varscan2
- FAT4 | c.12853G>A p.D4285N | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.992); catalogued as rs149301924; called by muse, mutect2
- FMO4 | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV63002044; called by muse, mutect2, varscan2
- GLDC | c.2962C>T p.R988W | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288008254; ClinVar: uncertain significance; called by muse, mutect2
- INA | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1045550149; called by muse, mutect2, varscan2
- KCNA10 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 102/322 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749237726; called by muse, mutect2, varscan2
- KCNA4 | c.614C>A p.P205H | Missense Mutation (SNP) | VAF 75/324 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV60252235; called by muse, mutect2, varscan2
- LSM10 | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.202); catalogued as COSV100240117; called by muse, mutect2, varscan2
- MARK2 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 80/233 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs763420975; called by muse, mutect2, varscan2
- OR10J1 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as rs368823977; called by muse, mutect2, varscan2
- OR11G2 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62131995; called by muse, mutect2, varscan2
- OR4C11 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs559156783, COSV56353261; called by muse, mutect2, varscan2
- OR6M1 | c.76T>A p.F26I | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV58434966; called by muse, mutect2, varscan2
- PCDHA12 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.16); catalogued as rs1554169943, COSV56518267; called by muse, mutect2
- SSRP1 | c.1142G>T p.R381L | Missense Mutation (SNP) | VAF 63/470 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53479521; called by muse, mutect2, varscan2
- SV2A | c.1638C>A p.F546L | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100974944; called by muse, mutect2, varscan2
- SYT4 | c.805G>C p.G269R | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54899814; called by muse, mutect2
- TAS1R2 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 104/306 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as rs772426504, COSV100946135, COSV64746583; called by muse, mutect2, varscan2
- TDRD12 | c.3386C>T p.T1129M (on ENST00000444215; = p.T1134M on NM_001366102.1) | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1173734709; called by muse, mutect2, varscan2
- TIMM50 | c.260-1G>A p.X87_splice | Splice Site (SNP) | VAF 53/163 reads (33%) | catalogued as rs1178478737; called by muse, mutect2, varscan2
- ZBED1 | c.2001G>T p.W667C | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV58139081; called by muse, mutect2, varscan2
- ZFHX4 | c.8692C>G p.R2898G | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.902); catalogued as COSV50482564; called by muse, mutect2, varscan2
- ZNF568 | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs576242825, COSV61743345; called by muse, mutect2, varscan2
- ADAT1 | c.13G>T p.D5Y | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AL441992.2 | c.641_644del p.I214Nfs*10 | Frame Shift Del (DEL) | VAF 40/206 reads (19%) | called by mutect2, pindel, varscan2
- ANPEP | c.387C>A p.Y129* | Nonsense Mutation (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- ARCN1 | c.1320G>T p.W440C | Missense Mutation (SNP) | VAF 148/499 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BBS10 | c.1061_1063del p.P354del | In Frame Del (DEL) | VAF 56/163 reads (34%) | called by pindel, varscan2
- C11orf97 | c.268T>A p.W90R | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CACNA1G | c.3191C>A p.P1064H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- CCNT2 | c.1685A>T p.E562V | Missense Mutation (SNP) | VAF 156/386 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.188); called by mutect2, varscan2
- CDC42BPG | c.2321A>T p.E774V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CEP104 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- CKAP4 | c.1708A>G p.N570D | Missense Mutation (SNP) | VAF 150/318 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- CLCN4 | c.1259C>G p.P420R | Missense Mutation (SNP) | VAF 98/158 reads (62%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP5 | c.1232A>T p.E411V | Missense Mutation (SNP) | VAF 15/467 reads (3%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.925); called by muse, mutect2
- CSMD3 | c.5528G>A p.S1843N (on ENST00000297405 / NM_001363185.1; = p.S1739N on NM_052900.3) | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNAH11 | c.9035_9037dup p.H3012_A3013insD | In Frame Ins (INS) | VAF 47/145 reads (32%) | called by mutect2, pindel, varscan2
- FAT3 | c.6404A>G p.N2135S | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT4 | c.6203T>C p.V2068A | Missense Mutation (SNP) | VAF 83/279 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- FCN1 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- IGKV2D-28 | c.335A>T p.Y112F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.544); called by mutect2, varscan2
- KCNJ9 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LAMB4 | c.1670A>C p.E557A | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MYH8 | c.1590A>T p.P530= | Splice Region (SNP) | VAF 17/290 reads (6%) | called by muse, mutect2
- NEUROD2 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NGLY1 | c.1543T>A p.S515T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NXF3 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.54); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OBSCN | c.8392G>A p.E2798K | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- OR10D3 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | called by muse, varscan2
- OR4D10 | c.880A>T p.M294L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2
- OR6F1 | c.535T>A p.C179S | Missense Mutation (SNP) | VAF 95/353 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIGQ | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- POLR1F | c.480G>T p.Q160H | Missense Mutation (SNP) | VAF 92/379 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PSG5 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 57/388 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- PSG6 | c.657del p.N220Tfs*3 | Frame Shift Del (DEL) | VAF 76/275 reads (28%) | called by mutect2, pindel, varscan2
- PXDNL | c.2946dup p.T983Hfs*38 | Frame Shift Ins (INS) | VAF 30/96 reads (31%) | called by mutect2, pindel, varscan2
- RPL5 | c.175_176del p.D59Yfs*53 | Frame Shift Del (DEL) | VAF 24/226 reads (11%) | called by pindel, varscan2
- RYR2 | c.14219C>A p.A4740D | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SCRIB | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 98/223 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC2A14 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- SNAP25 | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 81/251 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SPATA18 | c.1348G>T p.D450Y | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- STK11 | c.152del p.M51Rfs*13 | Frame Shift Del (DEL) | VAF 74/165 reads (45%) | called by mutect2, varscan2
- STK11 | c.157del p.D53Tfs*11 | Frame Shift Del (DEL) | VAF 67/233 reads (29%) | called by mutect2*, pindel, varscan2*
- SUPT5H | c.230T>G p.L77R | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TECTA | c.6440T>C p.F2147S | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TIFA | c.161A>G p.N54S | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRIM58 | c.114G>T p.R38S | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TUT1 | c.1205T>A p.L402Q | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ZBED1 | c.2002G>T p.G668C | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZDHHC22 | c.85C>G p.L29V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, varscan2
- ACSM2B | c.1224A>T p.G408= | Silent (SNP) | VAF 53/204 reads (26%) | called by muse, mutect2, varscan2
- ASTN1 | c.2898A>C p.A966= | Silent (SNP) | VAF 24/202 reads (12%) | called by muse, mutect2, varscan2
- CHAT | c.1344C>T p.I448= | Silent (SNP) | VAF 63/407 reads (15%) | catalogued as rs754253168, COSV60330129; called by muse, mutect2, varscan2
- EFR3B | c.249G>A p.L83= | Silent (SNP) | VAF 32/130 reads (25%) | called by muse, mutect2, varscan2
- EMP1 | c.75C>T p.A25= | Silent (SNP) | VAF 25/182 reads (14%) | catalogued as rs1041621738; called by muse, mutect2, varscan2
- FLG | c.3105C>A p.S1035= | Silent (SNP) | VAF 133/508 reads (26%) | called by muse, mutect2, varscan2
- FLNC | c.6990C>T p.G2330= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs113579230, COSV57953015; called by muse, mutect2, varscan2
- KALRN | c.6813G>T p.A2271= (on ENST00000360013 / NM_001024660.4; = p.A574= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/130 reads (42%) | called by muse, mutect2, varscan2
- KIF2C | c.60A>G p.Q20= | Silent (SNP) | VAF 51/208 reads (25%) | catalogued as rs1434971628, COSV64769015; called by muse, mutect2, varscan2
- MYH8 | c.5367G>A p.L1789= | Silent (SNP) | VAF 81/536 reads (15%) | called by muse, mutect2, varscan2
- OR1C1 | c.237C>A p.P79= | Silent (SNP) | VAF 91/203 reads (45%) | called by muse, mutect2, varscan2
- PCDHGB4 | c.1818G>T p.V606= | Silent (SNP) | VAF 48/183 reads (26%) | called by muse, mutect2, varscan2
- PDE3B | c.48G>T p.P16= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs1358249738; called by muse, mutect2, varscan2
- PIGT | c.34C>T p.L12= | Silent (SNP) | VAF 59/154 reads (38%) | called by muse, mutect2, varscan2
- PXDNL | c.2949G>T p.T983= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV62479769; called by mutect2, varscan2
- REM2 | c.156C>T p.D52= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV57465213; called by muse, mutect2, varscan2
- SPIRE1 | c.573A>T p.S191= | Silent (SNP) | VAF 78/231 reads (34%) | called by muse, mutect2, varscan2
- SRGAP3 | c.1203C>T p.A401= | Silent (SNP) | VAF 45/142 reads (32%) | called by muse, mutect2, varscan2
- STRN | c.483A>T p.L161= | Silent (SNP) | VAF 90/228 reads (39%) | called by muse, varscan2
- ZNF436 | c.219A>G p.V73= | Silent (SNP) | VAF 28/91 reads (31%) | called by muse, mutect2, varscan2
- AL359922.1 | c.348-35052G>A | Intron (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446316 G>T | 3'Flank (SNP) | VAF 56/213 reads (26%) | called by muse, mutect2, varscan2
- GPC1 | c.167-8333C>T | Intron (SNP) | VAF 7/54 reads (13%) | catalogued as rs1192458904; called by muse, mutect2, varscan2
- HSPA7 | n.510G>T | RNA (SNP) | VAF 60/150 reads (40%) | called by muse, mutect2, varscan2
- KIF6 | c.*18A>G | 3'UTR (SNP) | VAF 35/136 reads (26%) | catalogued as rs964080768; called by muse, mutect2, varscan2
- LINC02873 | n.87G>T | RNA (SNP) | VAF 48/174 reads (28%) | called by muse, mutect2, varscan2
- MGAM2 | c.5138-303C>A | Intron (SNP) | VAF 47/164 reads (29%) | called by muse, mutect2, varscan2
- MGAT4EP | n.1401G>T | RNA (SNP) | VAF 263/563 reads (47%) | called by muse, mutect2, varscan2
- PNMA8B | c.*1424T>C | 3'UTR (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- PPARG | c.819+35C>T | Intron (SNP) | VAF 15/124 reads (12%) | catalogued as rs375965554; called by muse, mutect2, varscan2
- RPGR | c.2520+841G>A | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, varscan2
- SLC2A9 | chr4:10025901 G>T | 5'Flank (SNP) | VAF 45/148 reads (30%) | called by muse, mutect2, varscan2
- SPAG11B | c.*103C>T | 3'UTR (SNP) | VAF 54/428 reads (13%) | catalogued as rs372253455; called by mutect2, varscan2
